Somatic mutation profile of tumor specimen TCGA-D8-A1JF-01A (aliquot TCGA-D8-A1JF-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79.9 years (29,199 days).
Specimen TCGA-D8-A1JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4bd1073-6b87-4548-810f-fe4ac4d9a188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JF-10A (Blood Derived Normal), aliquot TCGA-D8-A1JF-10A-01D-A17G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8487f8c0-28da-4315-b102-5a48d76c8798

The open-access MAF lists 49 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 30, Silent 10, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 1, In Frame Ins 1, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as COSV53724026; called by muse, mutect2, varscan2
- ANKRA2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV57141941; called by muse, mutect2, varscan2
- ANO6 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs781608617, COSV57668224; called by muse, mutect2, varscan2
- APCDD1L | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778135452, COSV64485356; called by muse, mutect2, varscan2
- ARID5B | c.2175G>C p.R725S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as COSV54430287; called by muse, mutect2, varscan2
- CELA3B | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as rs754087388, COSV61403042; called by muse, mutect2, varscan2
- CENPF | c.8963-2A>G p.X2988_splice | Splice Site (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100872032; called by muse, mutect2, varscan2
- CLCN5 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56586895; called by muse, mutect2, varscan2
- CLU | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV57068518; called by muse, mutect2, varscan2
- DLC1 | c.2882C>A p.P961H (on ENST00000276297 / NM_001348081.2; = p.P524H on NM_006094.5) | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs1372016357, COSV52328960; called by muse, mutect2, varscan2
- DMPK | c.353A>C p.E118A | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52182490; called by muse, mutect2, varscan2
- EGFR | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1219568637, COSV51781835; called by muse, mutect2, varscan2
- FHOD3 | c.1960T>G p.L654V (on ENST00000359247 / NM_001281739.3; = p.L671V on NM_025135.5) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.437); catalogued as COSV57189425; called by muse, mutect2, varscan2
- FO393400.1 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV54071615; called by muse, mutect2, varscan2
- GRM5 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59631336; called by muse, mutect2, varscan2
- MROH8 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54125376; called by muse, mutect2, varscan2
- MSGN1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as COSV55263925; called by muse, varscan2
- NGEF | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV50942687; called by muse, mutect2
- OR5I1 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56889248; called by muse, mutect2, varscan2
- PCDHA2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV65365967; called by muse, mutect2, varscan2
- PER1 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.968); catalogued as rs535351039, COSV57922167; called by muse, mutect2, varscan2
- PIK3CA | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs748197872, COSV55943795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAGE1 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV61013691; called by muse, mutect2, varscan2
- SCN2A | c.3431G>A p.S1144N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51856011; called by muse, mutect2, varscan2
- SH3RF3 | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193350267, COSV58685818; called by muse, mutect2
- SRSF11 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV63937893; called by muse, mutect2, varscan2
- TNRC6B | c.1504A>G p.M502V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs193065497, COSV57308342; called by muse, mutect2, varscan2
- USP10 | c.213G>T p.L71F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.249); catalogued as COSV54753241; called by muse, mutect2, varscan2
- VIL1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs750796385, COSV50288679; called by mutect2, varscan2
- ZNF564 | c.138dup p.W47Mfs*7 | Frame Shift Ins (INS) | VAF 22/50 reads (44%) | catalogued as rs754163760; called by mutect2, varscan2
- FAM122C | c.333del p.G112Afs*2 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- KIF21A | c.1967_1970dup p.K657Nfs*2 (on ENST00000361418 / NM_001378440.1; = p.K644Nfs*2 on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (INS) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- MROH1 | c.2692C>T p.H898Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NSDHL | c.307dup p.H103Pfs*10 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, pindel
- PASD1 | c.2225dup p.Q743Pfs*26 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by mutect2, pindel
- RADX | c.704del p.P235Lfs*5 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- UBAP2 | c.2746_2748dup p.P916dup | In Frame Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- CCNB3 | c.183A>C p.S61= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV52080083; called by muse, mutect2, varscan2
- DENND5B | c.2136A>G p.G712= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs992602187, COSV60908707; called by muse, mutect2, varscan2
- DSCAM | c.1626C>T p.N542= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV68036812; called by muse, mutect2, varscan2
- FNDC3B | c.3234A>G p.P1078= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs368498048; called by muse, mutect2, varscan2
- GRIPAP1 | c.210A>T p.V70= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV64553493; called by muse, mutect2, varscan2
- IL22RA2 | c.18C>T p.C6= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1395954958, COSV51664829; called by muse, mutect2, varscan2
- NUGGC | c.750C>G p.R250= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV100429840; called by muse, mutect2
- PTPN22 | c.1956A>T p.T652= (on ENST00000359785 / NM_001193431.2; = p.T597= on NM_012411.5) | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV63086769; called by muse, mutect2, varscan2
- TRAJ50 | c.33G>A p.G11= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1303567468; called by muse, mutect2, varscan2
- TRPV6 | c.1260T>C p.P420= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100844460; called by muse, mutect2
